Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A6BA, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A6BA-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REPORT

* Addendum

CC:

Patient

Clinical Diagnosis & History:
Leiomyosarcoma abdominal/pelvic.

Specimens Submitted:

- 1: SP: Radical resection of pelvis and retroperitoneal sarcoma, sigmoid resection and small bowel resection x 2 and resection of left ureter
- 2: SP: Left broad ligament
- 3: SP: Distal small bowel
- 4: SP: Resection of sigmoid

DIAGNOSIS:

- 1) SOFT TISSUE, PELVIS AND RETROPERITONEUM, SIGMOID COLON, SMALL BOWEL, AND LEFT URETER; RADICAL RESECTION:
- HIGH GRADE LEIOMYOSARCOMA, MEASURING 28 X 22 X 12 CM, WITH FOCAL NECROSIS (15%, MICROSCOPIC ASSESSMENT), AND A MITOTIC INDEX OF 28 MIT./10 HPF; MARGINS NOT INVOLVED.
- BENIGN SMALL AND LARGE BOWEL AND URETER.

NOTE: THE MORPHOLOGY OF THE TUMOR IN CONTEXT WITH THE PREVIOUSLY REPORTED IMMUNOPHENOTYPE FITS WELL WITH A LEIOMYOSARCOMA. A FEW IMMUNOSTAINS ARE PENDING TO VERIFY THE FINDINGS. RESULTS WILL BE REPORTED IN AN ADDENDUM.

- 2) SOFT TISSUE, LEFT BROAD LIGAMENT; RESECTION:
- BENIGN OVARY AND FALLOPIAN TUBE.
- 3) SMALL BOWEL, DISTAL; RESECTION:
- BENIGN SEGMENT OF SMALL BOWEL WITH ENDOMETRIOSIS.
- 4) COLON, SIGMOID; RESECTION:
- BENIGN SEGMENT OF SIGMOID COLON.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

** Continued on next page **

ICD O-3
Leiomyosarcoma 8890/3
Site Retroperitoneum
C48.0
JED 5/21/13

[page 2 of 4]
SURGICAL

Page 2 of 4

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh labeled, "radical resection of pelvic and retroperitoneal sarcoma, sigmoid resection and small bowel resection x 2 and resection of left ureter", and consists of one piece of irregularly shaped unoriented tan white soft tissue that measures 28 x 22 x 12 cm. The entire tumor is covered by a thin fibrous capsule and has a nodular appearance. There is a segment of small bowel identified attached to one side of the specimen that measures 11 cm in length and 2 cm in diameter. External surfaces of the tumor are inked black. Possible left ureter is identified attached to one side of the specimen that measures 7 cm in length and 0.5 cm in diameter. Attached to the other side of the tumor a segment of colon is identified that measures 13 cm in length and 2 cm in diameter. The lumen of the small bowel segment and colon are opened and no gross abnormalities are identified on the mucosal surfaces. The tumor is grossly not involving the wall of the small bowel loop or colon. Cut surface of the tumor is tan white trabeculated and firm. Focal necrosis is identified that involves less than 10% of the tumor. Hemorrhagic foci are identified. Multiple cyst formation is seen. Tissue is submitted to TPS. Gross photographs are taken.

Summary of sections:

UM--ureteral margin
SBM--small bowel margins
CM--colon margins
TM--tumor margins
T--tumor
TSB--tumor to small bowel
TC--tumor to colon

2.) The specimen is received fresh labeled "left broad ligament" and consists of a tan rubbery fibrous structure with attached fat measuring 4.6 x 3.5 x 1.3 cm. Sectioning reveals soft cut surface resembling ovarian stroma with scanty firm foci. A portion of fallopian tube measuring 2 cm in length by 0.5 cm in diameter is also present. Representative sections are submitted for permanent.

Summary of sections:

U--undesignated
F fallopian tube

3.) The specimen is received fresh labeled "distal small bowel" and consists of a portion of small bowel received closed at both ends without orientation measuring 22 cm in length by 4.5 cm and both circumferential surgical

** Continued on next page **

[page 3 of 4]
----- Page 3 of 4
margins, differentially inked blue and black. The serosal surface is focally fibrotic. Opening reveals tan glistening unremarkable mucosa. Representative sections are submitted.

Summary of sections:

SM1 blue surgical margin

SM2 black surgical margin

SI - small intestine, representative sections

4.) The specimen is received fresh labeled "resection of sigmoid" and consists of a portion of colon received closed at one end and open at the opposite end measuring 4.2 cm in length by 8.5 cm in circumference at both circumferential margins. The open margin is inked blue and the closed margin is inked green. Opening reveals tan glistening grossly unremarkable mucosa and underlying muscularis appears thickened. Representative sections are submitted.

Summary of sections:

SMC surgical margin, closed

SMO surgical margin, open

C colon, representative section

Summary of Sections:

Part 1: SP: Radical resection of pelvis and retroperitoneal sarcoma, sigmoid resection and small bowel resection x 2 and resection of left ureter

Block	Sect.	Site	PCs
2		CM	2
2		SBM	2
15		T	15
1		TC	1
6		TM	6
1		TSB	1
1		UM	1

Part 2: SP: Left broad ligament

Block	Sect.	Site	PCs
1		f	1
2		u	2

Part 3: SP: Distal small bowel

Block	Sect.	Site	PCs
2		si	2
1		sml	1

** Continued on next page **

[page 4 of 4]
1 sm2 1

Part 4: SP: Resection of sigmoid

Block	Sect.	Site	PCs
1		c	1
1		smc	1
1		smo	1

Procedures/Addenda:

Addendum

Date Ordered:

Status: Signed Out

Date Complete:

By:

Date Reported:

Addendum Diagnosis

PART 1:

- THE TUMOR CELLS ARE POSITIVE FOR SMA AND DESMIN. THEY ARE NEGATIVE FOR HMB-45.

NOTE: THE FINDINGS SUPPORT THE DIAGNOSIS OF LEIOMYOSARCOMA.

** End of Report **

Source: NCI Genomic Data Commons file 13f33d45-330a-4792-850d-89c1a85c0eaf (TCGA-DX-A6BA.BF14592F-1870-448A-8DA4-23495DAEE97D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).